TCGA case TCGA-24-2280 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Washington University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/97ad0360-3be4-401a-a94c-7f2800a1b519

Demographics
Sex at birth: female; Race: white; Age at index: 74 years; Vital status: Alive.

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 74.9 years (27,356 days); Year of diagnosis: 2004; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No; Days to last follow up: 2,143 days (5.9 years).
   Pathology details: Residual tumor measurement: 1-10 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 17 days; Days to treatment end: 178 days; Number of cycles: 8; Treatment dose: 4,240 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 17 days; Days to treatment end: 178 days; Number of cycles: 8; Treatment dose: 2,248 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Treatment intent type: Adjuvant; Days to treatment start: 17 days; Days to treatment end: 178 days; Number of cycles: 8; Treatment dose: 192 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 538 days (1.5 years); Days to treatment end: 766 days (2.1 years); Number of cycles: 8; Treatment dose: 478 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 906 days (2.5 years); Days to treatment end: 1,025 days (2.8 years); Treatment dose: 58 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 906 days (2.5 years); Days to treatment end: 1,025 days (2.8 years); Number of cycles: 6; Treatment dose: 2,882 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Initial disease status: Progressive Disease; Days to treatment start: 906 days (2.5 years); Days to treatment end: 1,025 days (2.8 years); Number of cycles: 6; Treatment dose: 599 mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 76.4 years (27,891 days); Days to diagnosis: 535 days (1.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 535 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 535 days (1.5 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 2,143 days (5.9 years); Disease response: With Tumor.
- ECOG performance status: 0; Timepoint: Post Adjuvant Therapy.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-24-2280-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 1.3; Shortest dimension: 0.4.
  Slide TCGA-24-2280-01A-01-TS1: Section location: Top; Percent tumor cells: 83; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 15.
  Slide TCGA-24-2280-01A-01-BS1: Section location: Bottom; Percent tumor cells: 88; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 10.
- Sample TCGA-24-2280-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Post-Adjuvant Therapy; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: Doxil.
- Drug treatment 3: Pharmaceutical therapy drug name: Avastin; Therapy regimen: Progression.
- Drug treatment 7: Pharmaceutical therapy drug name: Taxotere; Therapy regimen: Progression.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,143 days; disease-specific survival: no event (censored), 2,143 days; disease-free interval: event (new tumor event after initially disease-free), 535 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 535 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-24-2280-01A-01D-0704-01): tumor purity 0.59, ploidy 3.56, whole-genome doublings 2.
